Gene-level copy-number profile of tumor specimen TCGA-20-1687-01A from TCGA case TCGA-20-1687, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 46.4 years (16,961 days).
Specimen TCGA-20-1687-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.70d07271-15ef-4a45-aa05-421a65f61846.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-20-1687-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/08b72769-6ec9-46ed-bd1d-cd4b469c5684

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 887; copy number 2: 10,878; copy number 3: 18,711; copy number 4: 21,326; copy number 5: 5,024; copy number 6: 1,580; copy number 7: 387; copy number 8: 267; copy number 9: 445; copy number 10: 36; copy number 11: 253.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-20-1687-01A-01D-0559-01): tumor purity 0.76, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:71,525,233–71,931,199, 22 genes (within-gene range 0–1): CHST4, AC010547.2, RNU6-1061P, TAT-AS1, TAT, AC009097.2, MARVELD3, PHLPP2, AC009097.1, RNU6-208P, SNORA70D, AC009097.4, AC009097.3, AP1G1, SNORD71, AC010653.3, AC010653.1, ATXN1L, IST1, AC010653.2, ZNF821, AC009127.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 734 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,072,694–145,066,685, 342 genes, copy number 9–11 (broad region; genes not listed).
- chr10:110,869,743–133,761,125, 392 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 887. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
